Gene-level copy-number profile of tumor specimen TCGA-21-1079-01A from TCGA case TCGA-21-1079, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.7 years (26,176 days).
Specimen TCGA-21-1079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1b2a18eb-73d1-4253-9a9e-40be229b9f31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1079-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a31ddf8c-204b-4fc1-92ec-161dea33aeda

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 274; copy number 2: 9,888; copy number 3: 25,288; copy number 4: 15,195; copy number 5: 5,253; copy number 6: 2,828; copy number 7: 649; copy number 9: 444.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-21-1079-01): tumor purity 0.6, ploidy 3.41, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,093 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–39,424,868, 611 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:15,736,373–39,708,120, 444 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:66,511,556–68,119,209, 38 genes, copy number 7 (within-gene range 4–7): AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57.

Autosomal genes at a single copy (total copy number 1): 274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
